Somatic mutation profile of tumor specimen TCGA-HT-7857-01A (aliquot TCGA-HT-7857-01A-11D-2395-08) from TCGA case TCGA-HT-7857, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 24.4 years (8,912 days).
Specimen TCGA-HT-7857-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e4883bc-359b-48db-950e-460c38d2eaa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7857-10A (Blood Derived Normal), aliquot TCGA-HT-7857-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8974a39-237b-4b62-ad0f-a8138e0283d9

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, Nonsense Mutation 3, In Frame Del 1, 3'Flank 1, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs375507271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP22 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 15/158 reads (9%) | catalogued as COSV60526238; called by muse, mutect2
- EXOC4 | c.2888A>G p.K963R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV54094191; called by muse, mutect2, varscan2
- KIR3DL3 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 29/225 reads (13%) | catalogued as COSV99399907; called by muse, mutect2, varscan2
- KLHL25 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV61994880; called by muse, mutect2, varscan2
- NAA15 | c.248G>A p.W83* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV56719238; called by muse, mutect2, varscan2
- NF1 | c.3975-1G>A p.X1325_splice | Splice Site (SNP) | VAF 47/86 reads (55%) | catalogued as CS153440, COSV100647043, COSV62200559; called by muse, mutect2, varscan2
- OR10C1 | c.171G>T p.Q57H (on ENST00000622521; = p.Q55H on NM_013941.3) | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65822591; called by muse, mutect2, varscan2
- PTPN11 | c.213T>A p.F71L | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61005635, COSV61011607; called by muse, mutect2, varscan2
- TET2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV54407707; called by muse, mutect2, varscan2
- PLA2G15 | c.846_850del p.F282Lfs*22 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- PSME4 | c.2239_2241del p.P747del | In Frame Del (DEL) | VAF 18/90 reads (20%) | called by pindel, varscan2
- ABCA4 | c.1818C>A p.G606= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV64672943; called by muse, mutect2, varscan2
- ANKK1 | c.858C>T p.D286= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58271448; called by muse, mutect2, varscan2
- FMNL3 | c.2358T>C p.Y786= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs757103000, COSV53300937; called by muse, mutect2, varscan2
- NPAP1 | c.591C>T p.D197= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs371279086; called by muse, mutect2, varscan2
- UBR5 | c.8250C>T p.P2750= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV55284932; called by muse, mutect2, varscan2
- VPS9D1 | c.108C>T p.Y36= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs375598205; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271714 G>A | 3'Flank (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- RIBC1 | c.544+23C>T | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs1556893648, COSV99394976; called by muse, mutect2, varscan2
